Somatic mutation profile of tumor specimen TCGA-R6-A8WC-01A (aliquot TCGA-R6-A8WC-01A-11D-A37C-09) from TCGA case TCGA-R6-A8WC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 57.0 years (20,812 days).
Specimen TCGA-R6-A8WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fec62bd4-8dc8-4a3e-8e1f-22a2dbb41ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A8WC-10A (Blood Derived Normal), aliquot TCGA-R6-A8WC-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6f10e87-3cd4-44be-811e-1131868118dc

The open-access MAF lists 144 somatic variants for this specimen: 107 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 33, Nonsense Mutation 7, In Frame Del 5, Frame Shift Del 5, Frame Shift Ins 3, RNA 2, In Frame Ins 2, Intron 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 461/500 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 52/80 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0.241); catalogued as COSV65046911, COSV65048763; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 64/75 reads (85%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199604590, COSV63974984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP3 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748232602, COSV57421547; called by muse, mutect2, varscan2
- ANK1 | c.2789G>A p.R930H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1480924314; called by muse, mutect2, varscan2
- AWAT1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs373394760; called by muse, mutect2, varscan2
- CCDC186 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1205682825, COSV65161760; called by muse, mutect2, varscan2
- CFAP97 | c.307T>A p.L103M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV57110184; called by muse, mutect2, varscan2
- CHAT | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs146236256; called by muse, mutect2, varscan2
- CHRNB1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs202080837, COSV53438818; called by muse, mutect2, varscan2
- CNTNAP5 | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs779303965, COSV70491920; called by muse, mutect2, varscan2
- COL5A1 | c.4382C>T p.P1461L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880649, COSV65672999; called by muse, mutect2, varscan2
- DISP3 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); catalogued as rs759615246, COSV53821020; called by muse, mutect2, varscan2
- DNM1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57855499; called by muse, mutect2, varscan2
- EDEM1 | c.1594G>C p.A532P | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427262025; called by muse, mutect2, varscan2
- ESPL1 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs768297582, COSV99229998; called by muse, mutect2, varscan2
- FAAP100 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs754927886, COSV58367968; called by muse, mutect2, varscan2
- FNDC1 | c.2289G>A p.M763I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs761234995, COSV51931121, COSV51950822; called by muse, mutect2, varscan2
- FYB2 | c.1749A>C p.E583D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100599901; called by muse, mutect2, varscan2
- GOLGB1 | c.7417C>T p.R2473* | Nonsense Mutation (SNP) | VAF 38/75 reads (51%) | catalogued as rs770240812, COSV61466073; called by muse, mutect2, varscan2
- GRM1 | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.324); catalogued as rs377413746; called by muse, mutect2, varscan2
- H2AC8 | c.227_229del p.K76del | In Frame Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs780617468; called by pindel, varscan2
- IGHV1OR21-1 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs754881340; called by muse, mutect2
- IL9R | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV99729208; called by muse, mutect2, varscan2
- LINGO1 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1239872748; called by muse, mutect2, varscan2
- METTL17 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs148330410; called by muse, mutect2, varscan2
- MTMR3 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100071077; called by muse, mutect2, varscan2
- MYCT1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924076; called by muse, mutect2, varscan2
- MYH1 | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs764602423, COSV56853052; called by muse, mutect2, varscan2
- NEUROG1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV59083408; called by muse, mutect2, varscan2
- NRXN1 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as rs201881725, COSV58458700; called by muse, mutect2, varscan2
- NTRK3 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58125113, COSV58140678; called by muse, mutect2, varscan2
- OR5M3 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as rs148918177; called by muse, mutect2, varscan2
- PAPPA | c.3782C>T p.T1261M | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs538031087; called by muse, mutect2, varscan2
- PATZ1 | c.1590G>C p.E530D | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV56743083; called by muse, mutect2, varscan2
- PCDHA11 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as rs1554164920; called by muse, mutect2, varscan2
- PKD1 | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs376991027; called by muse, mutect2, varscan2
- PLXNB2 | c.4939G>A p.G1647R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs748677291; called by muse, varscan2
- RAPGEF4 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs773813929, COSV51382295; called by muse, mutect2, varscan2
- RYR3 | c.4415C>T p.A1472V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1177699207; called by muse, mutect2, varscan2
- SLC8A2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs764308545, COSV99369579; called by muse, mutect2, varscan2
- SNX25 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV53013545; called by muse, mutect2
- SOX17 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs200451706, COSV99810478; called by muse, varscan2
- STAT5B | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV53186308; called by muse, mutect2, varscan2
- TAS2R3 | c.513C>A p.F171L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV56091625; called by muse, mutect2, varscan2
- ZC3H13 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs1427607494, COSV54446991; called by muse, mutect2, varscan2
- ZNF567 | c.1840G>A p.E614K (on ENST00000536254 / NM_001322913.1; = p.E583K on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/42 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs763205267; called by muse, mutect2, varscan2
- ZSCAN10 | c.1786C>T p.R596C (on ENST00000252463; = p.R651C on NM_032805.3) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs781661100; called by muse, mutect2, varscan2
- ADAMTS2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS7 | c.4274C>T p.T1425I | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ADGRL3 | c.1397C>A p.S466* (on ENST00000506720 / NM_001322402.2; = p.S398* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- ATP6V0A1 | c.1244T>C p.L415S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMP3 | c.534A>C p.Q178H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BNC1 | c.1733A>G p.E578G | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C10orf90 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- C12orf40 | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CDH11 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CDKN2A | c.32_42del p.P11Lfs*29 | Frame Shift Del (DEL) | VAF 20/26 reads (77%) | called by mutect2, pindel, varscan2
- CLCN7 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNOT7 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- COL12A1 | c.7063G>T p.E2355* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- CSMD1 | c.9054del p.H3019Ifs*18 (on ENST00000520002; = p.H3018Ifs*18 on NM_033225.6) | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- DGKB | c.921C>T p.V307= | Splice Region (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- DNAH5 | c.5767T>C p.Y1923H | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHF | c.759G>C p.K253N | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3K | c.453_455dup p.Q151dup | In Frame Ins (INS) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- FAT4 | c.12041T>A p.L4014H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GIT1 | c.116_151del p.R39_H50del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel
- HMCN1 | c.14564G>A p.G4855E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPH3 | c.21_22del p.H7Qfs*5 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNG1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNJ15 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNN2 | c.757G>T p.D253Y (on ENST00000264773; = p.D465Y on NM_021614.4) | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KLHL10 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 235/574 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP5-7 | c.338A>T p.Q113L | Missense Mutation (SNP) | VAF 169/241 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, varscan2
- LRCH1 | c.1346_1347dup p.A450* | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- LRFN5 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LRRC45 | c.198_203del p.D67_C68del | In Frame Del (DEL) | VAF 32/67 reads (48%) | called by mutect2, pindel, varscan2
- MICAL3 | c.4422del p.K1475Sfs*130 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- MMP23B | c.1021_1022dup p.E342Wfs*16 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- MOCS1 | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPG | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSH3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MSTN | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB7 | c.1223A>C p.E408A | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCID2 | c.807_808insGAA p.E269dup | In Frame Ins (INS) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- PCLO | c.11260del p.T3754Pfs*13 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | called by mutect2, pindel, varscan2
- PLEKHN1 | c.1444A>G p.T482A (on ENST00000379409; = p.T430A on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RADIL | c.178T>C p.S60P | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RFXAP | c.188dup p.S64Qfs*9 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- RORB | c.485A>G p.K162R (on ENST00000396204 / NM_001365023.1; = p.K151R on NM_006914.4) | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- RS1 | c.382_384del p.K128del | In Frame Del (DEL) | VAF 20/37 reads (54%) | called by mutect2, pindel, varscan2
- SCN11A | c.5109G>T p.M1703I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SGK1 | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC39A10 | c.1452A>C p.E484D | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT tolerated (0.56); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- SLFN12 | c.965G>A p.W322* | Nonsense Mutation (SNP) | VAF 45/67 reads (67%) | called by muse, mutect2, varscan2
- SMAD4 | c.1017T>A p.F339L | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMAD4 | c.1479_1481del p.D494del | In Frame Del (DEL) | VAF 18/23 reads (78%) | called by pindel, varscan2
- SPEF2 | c.667A>C p.N223H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TLL1 | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TRMT13 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UNC5C | c.2627A>T p.D876V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF462 | c.4912G>A p.E1638K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF628 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ABHD17A | c.474C>T p.S158= (on ENST00000292577 / NM_001130111.2; = p.S209= on NM_031213.4) | Silent (SNP) | VAF 64/79 reads (81%) | catalogued as rs747887237, COSV99171434; called by muse, mutect2, varscan2
- ALDOC | c.774T>C p.R258= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- ARMC5 | c.2688G>A p.R896= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- ATP2B2 | c.2016G>A p.P672= (on ENST00000352432; = p.P638= on NM_001683.5) | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs768140147, COSV100659592; called by muse, mutect2, varscan2
- BICRAL | c.2508G>A p.E836= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs548782383; called by muse, mutect2, varscan2
- CAPN13 | c.1962A>T p.G654= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.1509G>A p.S503= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs369464938; called by muse, mutect2, varscan2
- CHTF18 | c.2196G>A p.Q732= | Silent (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- CPSF6 | c.1125C>T p.S375= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs752501123; called by muse, mutect2, varscan2
- CRELD2 | c.1039C>T p.L347= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- DKC1 | c.1533G>A p.L511= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, varscan2
- DNAH11 | c.219G>A p.T73= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs1051931486; called by muse, mutect2, varscan2
- FBF1 | c.2655C>T p.A885= (on ENST00000586717; = p.A899= on NM_001319193.1) | Silent (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- FLT1 | c.462C>T p.L154= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs867147591, COSV56716902; called by muse, mutect2, varscan2
- HOPX | c.15C>T p.T5= (on ENST00000317745; = p.T23= on NM_032495.6) | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs11555051, COSV58499883; called by muse, mutect2, varscan2
- ITPR3 | c.3684G>A p.T1228= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs543118868, COSV100967089; called by muse, mutect2, varscan2
- KRT1 | c.1740C>T p.S580= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as rs771998586; called by muse, mutect2, varscan2
- LRRC4C | c.846G>T p.L282= | Silent (SNP) | VAF 24/27 reads (89%) | called by muse, mutect2, varscan2
- LY75 | c.1482C>T p.D494= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs141523249; called by muse, mutect2, varscan2
- LY86 | c.102C>T p.S34= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs144373281; called by muse, mutect2, varscan2
- MAFF | c.207C>T p.R69= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- NCR1 | c.774G>T p.R258= | Silent (SNP) | VAF 34/39 reads (87%) | called by muse, mutect2, varscan2
- NLRP12 | c.2475C>G p.T825= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- OR2C3 | c.675C>T p.A225= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs149975458; called by muse, mutect2, varscan2
- OR2T33 | c.579C>T p.F193= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs1439477620, COSV58815866; called by muse, mutect2, varscan2
- PRKDC | c.8244T>C p.V2748= | Silent (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- RXFP3 | c.882C>T p.I294= | Silent (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4978C>T p.L1660= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- SOBP | c.1230C>T p.P410= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- TADA2B | c.309C>T p.P103= | Silent (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- TMC8 | c.2058C>T p.H686= | Silent (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- TNFAIP8L3 | c.660C>T p.N220= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as rs764189445, COSV59529504; called by muse, mutect2, varscan2
- TRIM42 | c.1500A>G p.S500= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV53882231; called by muse, mutect2, varscan2
- AC244258.1 | n.716T>G | RNA (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- LARP7 | c.1142+558T>C | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as rs767302290; called by muse, mutect2, varscan2
- SLURP2 | c.-1C>A | 5'UTR (SNP) | VAF 68/118 reads (58%) | catalogued as COSV58187388; called by muse, mutect2, varscan2
- SSPOP | n.12468dup | RNA (INS) | VAF 59/130 reads (45%) | catalogued as rs947262596; called by mutect2, pindel, varscan2
